Somatic mutation profile of tumor specimen TCGA-OY-A56Q-01A (aliquot TCGA-OY-A56Q-01A-11D-A403-09) from TCGA case TCGA-OY-A56Q, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 78.4 years (28,623 days).
Specimen TCGA-OY-A56Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86219fb7-5c10-42ef-ac95-3df8adfaa10a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OY-A56Q-10A (Blood Derived Normal), aliquot TCGA-OY-A56Q-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20f2bcf9-9f45-4cfa-91ec-fce7cf38b464

The open-access MAF lists 56 somatic variants for this specimen: 45 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 10, Frame Shift Del 3, Splice Site 2, In Frame Del 1, Intron 1, Splice Region 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.981T>G p.Y327* | Nonsense Mutation (SNP) | VAF 20/20 reads (100%) | catalogued as rs879254077, COSV52678878, COSV52914365, COSV52993701; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AHNAK | c.8131G>C p.D2711H | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57225976, COSV99949712; called by muse, mutect2, varscan2
- AL031777.2 | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100587280; called by muse, mutect2
- ANKZF1 | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs754953343, COSV99850925; called by mutect2, varscan2
- APOBR | c.57G>A p.L19= | Splice Region (SNP) | VAF 9/49 reads (18%) | catalogued as rs1024974013, COSV100112949; called by muse, mutect2, varscan2
- BCAR1 | c.2120T>G p.L707R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99367411; called by muse, mutect2, varscan2
- C2orf42 | c.971C>G p.A324G | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as rs747430871; called by muse, varscan2
- CCDC163 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV101284480; called by muse, mutect2, varscan2
- CDC42BPB | c.2311G>C p.D771H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV100775636; called by muse, mutect2, varscan2
- CES3 | c.1601G>T p.R534L | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.157); catalogued as COSV100310058, COSV57592909; called by muse, mutect2, varscan2
- CLIP3 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as rs1157489253, COSV100859371; called by muse, mutect2
- COX10 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV55404332, COSV99886254; called by muse, mutect2, varscan2
- DCAF1 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs371807205; called by muse, mutect2
- DCAF15 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); catalogued as rs1424431775, COSV99586493; called by muse, mutect2
- ELOA2 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as COSV99798226; called by muse, mutect2, varscan2
- ENPP6 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.133); catalogued as rs745567557, COSV99699161; called by muse, mutect2, varscan2
- GABRQ | c.484G>A p.V162M | Missense Mutation (SNP) | VAF 10/11 reads (91%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV100941280, COSV100941437; called by muse, mutect2, varscan2
- HGSNAT | c.1724C>G p.P575R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99925519; called by muse, mutect2, varscan2
- HUWE1 | c.1862T>C p.F621S | Missense Mutation (SNP) | VAF 29/32 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99474320; called by muse, mutect2, varscan2
- KANK1 | c.2564C>T p.P855L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100620109; called by muse, mutect2
- KCNH1 | c.2020C>T p.R674W (on ENST00000271751 / NM_172362.3; = p.R647W on NM_002238.4) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754794236, COSV55077331; called by muse, mutect2, varscan2
- KIAA1109 | c.1007G>T p.G336V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99177057; called by muse, mutect2, varscan2
- LAMA1 | c.5245G>A p.A1749T | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.193); catalogued as COSV101057827; called by muse, mutect2, varscan2
- MRM2 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs201350897; called by muse, mutect2, varscan2
- MYO1E | c.2120G>A p.R707K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.217); catalogued as COSV99896675; called by muse, mutect2, varscan2
- NSF | c.1361A>G p.N454S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.282); catalogued as COSV99834052; called by muse, mutect2, varscan2
- NUBP2 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.773); catalogued as rs199651045; called by muse, mutect2, varscan2
- OR56B1 | c.818C>G p.T273R | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV100402742; called by muse, mutect2, varscan2
- PCDHA11 | c.1499A>C p.D500A | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.103); catalogued as COSV100254811; called by muse, mutect2, varscan2
- PTPRU | c.2348+1G>A p.X783_splice | Splice Site (SNP) | VAF 11/45 reads (24%) | catalogued as rs760447683, COSV60521097, COSV99057688; called by muse, mutect2
- PZP | c.3128G>C p.G1043A | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.932); catalogued as COSV99739564; called by muse, mutect2, varscan2
- RIC8A | c.1282G>A p.G428R (on ENST00000526104 / NM_001286134.1; = p.G434R on NM_021932.5) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1284813484, COSV100291586; called by muse, mutect2, varscan2
- RIPOR2 | c.1337A>T p.H446L | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as COSV99430143; called by muse, mutect2
- SMCO1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs987006207, COSV101285034; called by muse, mutect2, varscan2
- SMG9 | c.883C>T p.L295F | Missense Mutation (SNP) | VAF 28/232 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as rs1469299834, COSV99526945; called by muse, mutect2, varscan2
- TECPR2 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs368485063; called by muse, mutect2, varscan2
- TRPM6 | c.4379G>A p.G1460D | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as COSV100667008; called by muse, mutect2, varscan2
- WNK3 | c.3855C>A p.S1285R | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100672170; called by muse, mutect2, varscan2
- XPNPEP3 | c.1236+1G>A p.X412_splice | Splice Site (SNP) | VAF 10/44 reads (23%) | catalogued as rs770065955, COSV100782358; called by muse, mutect2, varscan2
- ANKRD17 | c.2727_2732del p.G910_L911del | In Frame Del (DEL) | VAF 4/21 reads (19%) | called by mutect2, pindel, varscan2
- C2orf42 | c.956_965del p.L319Qfs*4 | Frame Shift Del (DEL) | VAF 16/116 reads (14%) | called by pindel, varscan2
- IGKV1D-16 | c.70A>T p.I24F | Missense Mutation (SNP) | VAF 25/202 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- MSX2 | c.562del p.I188Sfs*21 | Frame Shift Del (DEL) | VAF 11/55 reads (20%) | called by mutect2, pindel, varscan2
- PTGS2 | c.1295_1296del p.K432Sfs*7 | Frame Shift Del (DEL) | VAF 15/120 reads (13%) | called by mutect2, pindel, varscan2
- SEC23B | c.1784_1785dup p.N596Lfs*20 | Frame Shift Ins (INS) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- ABHD17A | c.744C>T p.L248= (on ENST00000292577 / NM_001130111.2; = p.L299= on NM_031213.4) | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs1332250270, COSV99171388; called by muse, mutect2, varscan2
- ADCY5 | c.2721C>T p.P907= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as rs143322376; called by muse, mutect2, varscan2
- C2orf78 | c.1263G>A p.K421= | Silent (SNP) | VAF 21/64 reads (33%) | catalogued as rs1274285368, COSV68516621; called by muse, mutect2, varscan2
- CTNND2 | c.1497C>T p.Y499= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as rs1207977054, COSV58880564; called by muse, mutect2, varscan2
- EPB41L3 | c.1377C>A p.I459= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100550359; called by muse, mutect2, varscan2
- NMT2 | c.1434T>C p.Y478= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV100975649; called by muse, mutect2, varscan2
- PCDHB4 | c.2115C>T p.L705= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV99522522; called by muse, mutect2, varscan2
- TET3 | c.4626C>T p.F1542= | Silent (SNP) | VAF 17/125 reads (14%) | catalogued as COSV101328124; called by muse, mutect2, varscan2
- TRAV9-1 | c.31C>T p.L11= | Silent (SNP) | VAF 56/56 reads (100%) | called by muse, mutect2, varscan2
- TRMO | c.1035C>T p.A345= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs770775804, COSV64292309; called by muse, mutect2, varscan2
- BRSK2 | c.1939+270C>A | Intron (SNP) | VAF 19/86 reads (22%) | catalogued as rs745694954, COSV100373197; called by muse, mutect2, varscan2
